TCGA case TCGA-DX-A6YQ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6037a772-38a4-4f44-95a5-681f90b81684

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 86 years; Vital status: Dead; Days to death: 93 days.

Diagnoses (1)
1. Fibromyxosarcoma: ICD-O-3 morphology code: 8811/3; ICD-10 code: C49.5; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of pelvis; Classification of tumor: primary; Age at diagnosis: 86.0 years (31,421 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.3; Tumor length measurement: 14.5; Tumor width measurement: 8.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 25; Necrosis present: Yes; Tumor depth descriptor: Deep.

Follow-up (1 entry)
- Days to follow up: 93 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 21.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A6YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 390 mg.
  Slide TCGA-DX-A6YQ-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A6YQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A6YQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Site of primary tumor other: Buttock; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Other (please specify.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 8.0.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 93 days; disease-specific survival: no event (censored), 93 days; disease-free interval: no event (censored), 93 days; progression-free interval: no event (censored), 93 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A6YQ-01A-12D-A33D-01): tumor purity 0.69, ploidy 2.8, whole-genome doublings 1.
